Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6542, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6542-01A (Primary Tumor).

[page 1 of 5]
TCGA-DU-6542

Surgical Pathology Report

Taken:
Received:
Reported:

CLINICAL HISTORY
Brain tumor.

OPERATIVE DIAGNOSES

Operation/Specimen: A: Right temporal tumor, excision biopsy
B: Deep temporal tumor, excision biopsy
C: Posterior temporal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, right temporal tumor, excision biopsy: Glioblastoma with oligodendroglial component (WHO Grade IV) (see comment).

B. Brain, deep temporal tumor, excision biopsy: Glioblastoma with oligodendroglial component (WHO Grade IV).

C. Brain, posterior temporal tumor, excision biopsy: Glioblastoma with oligodendroglial component (WHO Grade IV).

COMMENT

All specimens show similar features and will be described together.
Sections
show a high-grade glioma demonstrating mitotic activity, microvascular proliferation and geographic necrosis. Many cells have round nuclei very much
resembling an oligodendroglioma. Other cells are more astrocyte- or gemistocytic astrocyte-like in appearance. Some cells are intermediate between
mini-gemistocytes and classic gemistocytes. Hermelin slides are also examined
and show some mucin pools. The tumor is diffusely p53 positive and the Ki-67
labeling index is up to approximately 30%. Positive and negative controls show
appropriate immunoreactivity.
Electronically Signed Out

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)
Date Ordered: Date Reported:

[page 2 of 5]
Interpretation

POSITIVE: Allelic loss on chromosome arm 19q is detected.

No deletion of chromosome arm 1p seen.

Informative loci are: D1S548, D1S1592, D1S552, D19S219, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block.

DNA extracted from a corresponding blood specimen was used as normal reference control.

H slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by [REDACTED]. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

Electronically Signed Out

[REDACTED]

[page 3 of 5]
[REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block.

H slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by [REDACTED]. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

[REDACTED]

NEGATIVE - No evidence of EGFRvIII mutation is detected

[page 4 of 5]
Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

GROSS DESCRIPTION

A. Right temporal tumor, excision biopsy:
CONTAINER LABEL: Right temporal tumor
FIXATIVE: Formalin. NO. PIECES: 1 tan, glistening tissue fragment.
SIZE/VOL:

[page 5 of 5]
3.0 x 2.2 x 2.2 cm. CASSETTES: 5, [REDACTED]
B. Deep temporal tumor, excision biopsy:
CONTAINER LABEL: Deep temporal tumor
FIXATIVE: Formalin. NO. PIECES: 1 hemorrhagic, ragged, tan, tissue
fragment.
SIZE/VOL: 2.8 x 2.2 x 1.2 cm. CASSETTES: 3, [REDACTED]
C. Posterior temporal tumor, excision biopsy:
CONTAINER LABEL: Posterior temporal tumor
FIXATIVE: Formalin. NO. PIECES: 2 tan-brown, ragged tissue fragments.
SIZE/VOL: 2.2 x 2.0 x 0.6 cm. CASSETTES: 3, [REDACTED] [REDACTED]

[REDACTED]
ICD-9(s):
191.9 191.9

[REDACTED]
EGFRvIII [REDACTED]
[REDACTED]

Histo Data

Part A: Right temporal tumor, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]
Stain/cnt	Block Ordered Comment
H/E x 1	1 [REDACTED]
H/E x 1	2 [REDACTED]
H/E x 1	3 [REDACTED]
MIB1-DA x 1	3 [REDACTED]
P53DO7 x 1	3 [REDACTED]
H/E x 1	4 [REDACTED]
H/E x 1	5 [REDACTED]

Part B: Deep temporal tumor, excision biopsy

Taken: [REDACTED] 00:00	Received: [REDACTED]
Stain/cnt	Block Ordered Comment
H/E x 1	1 [REDACTED]
H/E x 1	2 [REDACTED]
H/E x 1	3 [REDACTED]

Part C: Posterior temporal tumor, excision biopsy

Taken: [REDACTED] 00:00	Received: [REDACTED]
Stain/cnt	Block Ordered Comment
H/E x 1	1 [REDACTED]
EGFR vIII-curls x 1	2 [REDACTED]
H/E x 1	2 [REDACTED]
LOH-curls x 1	2 [REDACTED]
MGMT-curls x 1	2 [REDACTED]
H/E x 1	3 [REDACTED]

*** End of Report ***

Source: NCI Genomic Data Commons file c175360a-9504-447b-b897-9ba07c19cd5b (TCGA-DU-6542.BD0D6D1B-BDCD-4C33-9ADC-ECF34CE24D6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).